Gene-level copy-number profile of tumor specimen TCGA-VS-A8EJ-01A from TCGA case TCGA-VS-A8EJ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 60.2 years (22,000 days).
Specimen TCGA-VS-A8EJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.7bd324d6-ed82-4278-a102-5f0008b57ae1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VS-A8EJ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/90784c9d-a197-4452-a64f-027b66a697f0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 125; copy number 1: 3,744; copy number 2: 26,892; copy number 3: 17,116; copy number 4: 8,457; copy number 5: 2,531; copy number 6: 389; copy number 7: 263; copy number 8: 260; copy number 9: 38.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VS-A8EJ-01A-11D-A37M-01): tumor purity 0.92, ploidy 2.69, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,361 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:237,042,184–237,833,988, 1 gene, copy number 5 (within-gene range 4–5): RYR2.
- chr1:237,471,119–240,776,824, 49 genes, copy number 5: MIR4428, AL442065.1, AL359924.1, ZP4, AL590396.1, MTCO1P38, AL590396.2, AL590396.3, MTRNR2L11, MTCYBP15, MTND6P15, MTND5P18, YWHAQP9, AL356010.2, AL356010.1, RNU6-725P, LINC01139, AL359551.1, KRT18P32, MIPEPP2, AL583825.1, AL590135.1, AC093426.2, AC093426.1, CHRM3, CHRM3-AS2, CHRM3-AS1, AL356361.2, AL356361.1, AL356361.3, RPS7P5, FMN2, AL359918.1, Y_RNA, ADH5P3, AL359918.2, Y_RNA, AL590490.1, GREM2, AL358176.1, AL358176.2, AL358176.4, AL358176.3, RNU5F-8P, AL358176.5, Y_RNA, AL365184.2, AL365184.1, THAP12P8.
- chr1:240,823,006–240,823,433, 1 gene, copy number 5: RFKP1.
- chr2:82,814,984–84,350,774, 14 genes, copy number 7: MTND4P25, MTND5P27, MTND6P7, MTCYBP7, AC098817.1, DHFRP3, AC138623.1, LINC01809, RPL37P10, RNU6-1312P, CRLF3P3, ST6GALNAC2P1, FUNDC2P2, AC106874.1.
- chr2:140,231,423–142,131,016, 1 gene, copy number 5 (within-gene range 3–5): LRP1B.
- chr2:141,167,257–141,208,376, 2 genes, copy number 5: RNU6-904P, RPS16P3.
- chr3:154,651,656–181,836,880, 379 genes, copy number 5–9 (within-gene range 2–9) (broad region; genes not listed).
- chr4:157,879,902–190,092,279, 426 genes, copy number 5–6 (within-gene range 2–6) (broad region; genes not listed).
- chr5:58,198–40,067,200, 618 genes, copy number 5–8 (broad region; genes not listed).
- chr6:10,423,140–55,282,620, 1,300 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr6:66,710,242–67,210,480, 3 genes, copy number 5: AL450336.1, RNU7-66P, AL591004.1.
- chr8:41,032,892–43,674,591, 81 genes, copy number 8 (broad region; genes not listed).
- chr8:82,033,533–84,164,564, 13 genes, copy number 5 (within-gene range 4–5): AC060765.2, LINC02839, HNRNPA1P4, AC060765.1, AC105031.2, AC105031.1, AC090095.1, AC090132.1, AC090132.2, LINC01419, AC015522.1, TPM3P3, AC012400.1.
- chr8:91,909,738–115,809,673, 359 genes, copy number 5–7 (broad region; genes not listed).
- chr8:116,022,686–116,022,779, 1 gene, copy number 6: RNA5SP276.
- chr8:117,520,713–119,673,453, 22 genes, copy number 5: MED30, RPS10P16, EXT1, SAMD12, AC023590.1, SAMD12-AS1, RPS26P35, TNFRSF11B, RNU6-12P, AC107953.1, COLEC10, AC107953.2, MAL2, MAL2-AS1, MIR548AZ, AC021733.4, AC021733.1, CCN3, AC021733.2, AC021733.3, ENPP2, CYCSP23.
- chr8:135,742,343–138,497,261, 12 genes, copy number 5: RNU1-35P, LINC02055, AC103955.1, AC023781.1, RNU6-144P, ZYXP1, AC105213.1, AC110053.1, AC046195.1, AC046195.2, AC079015.1, FAM135B.
- chr11:39,024,631–42,253,721, 20 genes, copy number 5: AC021723.2, AC021723.1, RNU6-99P, AC021749.1, AC021820.1, AC080100.1, LRRC4C, Y_RNA, AC090720.1, RNU6-365P, AC090138.1, LINC02741, AC021006.1, AC021006.2, LINC01499, AC023442.1, AC023442.3, AC023442.2, LINC02745, LINC02740.
- chr13:38,821,798–38,936,199, 3 genes, copy number 5: FREM2-AS1, PLA2G12AP2, ANKRD26P2.
- chr17:32,492,522–32,877,177, 1 gene, copy number 5 (within-gene range 2–5): MYO1D.
- chr17:32,627,739–32,945,106, 5 genes, copy number 5 (within-gene range 2–5): AC025211.1, Y_RNA, AC084809.1, AC084809.2, TMEM98.
- chr17:40,473,554–40,885,242, 22 genes, copy number 5: AC018629.1, TNS4, AC004585.1, CCR7, AC004585.2, SMARCE1, AC073508.2, AC073508.3, KRT222, AC073508.1, KRT24, KRT223P, KRT25, KRT26, KRT27, KRT28, AC090283.1, KRT10, TMEM99, AC004231.4, KRT12, KRT20.
- chr17:56,471,142–56,595,611, 3 genes, copy number 5: AC006600.2, RPL39P33, NOG.
- chr18:11,609,596–11,670,165, 7 genes, copy number 5: SLC35G4, AP001120.4, NPIPB1P, AP001120.2, AP001120.3, MIR7153, AP001120.1.
- chr18:27,335,968–27,595,164, 1 gene, copy number 5 (within-gene range 4–5): AC090403.1.
- chr18:27,418,884–30,414,073, 17 genes, copy number 5: RBM22P1, PA2G4P3, AC068408.2, AC090936.1, CDH2, AC110015.1, AC006249.1, AC090365.1, ARIH2P1, AC023932.1, RNU6-408P, AC105245.1, AC074237.1, AC117569.1, AC117569.2, AC115100.1, MIR302F.

Autosomal genes at a single copy (total copy number 1): 2,420. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
